Surgical pathology report (de-identified scan), TCGA case TCGA-23-1121, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1121-01A (Primary Tumor).

[page 1 of 3]
***** AMENDED REPORT *****

Reason for Amendment/Correction #1: Typographical errors

DIAGNOSIS:

A. UTERUS, RIGHT AND LEFT FALLOPIAN TUBES AND OVARIES, SUPRACERVICAL HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY:

- High-grade müllerian carcinoma, serous type, with extensive necrosis, involving:
- The full thickness of uterine wall
- The entire left ovary and fallopian tube
- The right fallopian tube mucosa and paratubal soft tissue
- Perineural infiltration and lymphatic vessel invasion by tumor is present
- Benign right ovary with serous inclusion glands
- The non-neoplastic endometrium is non-phasic/atrophic
- The uninvolved myometrium shows leiomyoma

B. LEFT PELVIC LYMPH NODE, BIOPSY:

- High-grade müllerian carcinoma, serous type, replacing almost the entire lymph node parenchyma (1/1)

C. CERVIX, RESECTION:

- High-grade müllerian carcinoma involving outer cervical wall
- The intact ectocervical and endocervical mucosa appear free of tumor

D. PARAMETRIAL TUMOR, EXCISION:

- High-grade müllerian carcinoma, serous type

E. SUPRACOLIC OMENTUM IMPLANT, EXCISION:

- High-grade müllerian carcinoma, serous type

pTNM staging: T3cN1Mx.

HISTORY: Pelvic mass. ([REDACTED]) abdominal discomfort. CT of abdomen and pelvis demonstrated a 14.0 cm solid and cystic pelvic mass with possible adnexal origin. CA 125 with 519 and CEA with 7.8)

MICROSCOPIC:

See diagnosis.

GROSS:

A. TAH BSO

Labeled with patient's name, labeled [REDACTED] and received in formalin is a supracervical hysterectomy with bilateral salpingo-oophorectomy specimen. The uterus measures 5.0 cm from fundus to cervical resection margin,

[page 2 of 3]
[REDACTED]
AMENDED REPORT

PATIENT: [REDACTED]

PATH #: [REDACTED]

4.0 cm from cornu to cornu, and 3.3 cm from anterior to posterior. There are three intramural tan-white firm spherical masses with whorled cut surfaces ranging from 0.6 up to 1.2 cm in greatest dimension. The uterine serosa is tan-pink and smooth. The endometrial cavity measures 3.0 cm in length, 1.0 cm in width and is lined by a smooth endometrium.

A partially cystic and solid tan-yellow mass measuring 12.5 x 11.0 x 9.5 cm is replacing the entire left ovary and fallopian tube. No residual left ovary or fallopian tube is identified.

The right ovary measures 3.0 x 1.0 x 0.5 cm and is grossly unremarkable. The right fimbriated fallopian tube measures 9.0 cm in length, 0.6 cm in diameter, and is grossly unremarkable. A tan firm partially hemorrhagic tumor measuring 5.0 x 3.0 x 2.0 cm is involving right paratubal soft tissue.

The endometrium is grossly unremarkable.

Representative sections are submitted.

Summary of sections:

- A1-A7. Left adnexal mass - multiple
- A8. Anterior corpus - 1
- A9. Posterior corpus - 1
- A10. Right fallopian tube and adnexa - 3
- A11. Right fallopian tube at interface with lesion - 1
- A12. Right ovary - 1
- A13. Right paratubal lesion - 1
- A14. Frozen section control for FS 1
- A14-A15. Uterine corpus - 1 each
- A16-A17. Uterine corpus - 1 each
- A18-A19. Right fallopian tube - 1 each

B. LEFT PELVIC LYMPH NODE

Labeled with patient's name, labeled "left pelvic lymph node", and received in formalin is a tan-pink lymph node measuring 2.9 x 1.5 x 1.3 cm. Entirely submitted.

B1, B2. Lymph node, bisected - 1 each

C. CERVIX

Labeled with patient's name, labeled "cervix", and received in formalin is an amputated cervix measuring 3.5 cm in width and 2.5 cm in length. The cervical os is patent measuring 0.3 cm. The mucosal lining of the ectocervix and endocervix are grossly unremarkable. Representative sections are submitted.

- C1. Quadrant 1 cervix - 1
- C2. Quadrant 1 parametrium - 1
- C3. Quadrant 2 cervix - 1
- C4. Quadrant 3 parametrium - 1
- C5. Quadrant 3 cervix - 1
- C6. Quadrant 4 cervix - 1

D. PARAMETRIAL TUMOR

Labeled with patient's name, labeled "parametrial tumor", and received in formalin are four tan-pink hemorrhagic soft tissue fragments ranging from 1.0 up to 1.5 cm in greatest dimension. Entirely submitted.

D1. 4

E. SUPRACOLIC OMENTUM IMPLANT

Labeled with patient's name, labeled "supracolic omentum implant", and received in formalin is a tan firm nodule measuring 4.5 x 2.9 x 2.5 cm with a small amount of attached soft yellow lobulated adipose tissue.

[page 3 of 3]
***** AMENDED REPORT *****

PATIENT: [REDACTED]

PATH #: [REDACTED]

Representative sections are submitted.
E1. 3

OPERATIVE CALL
OPERATIVE CONSULT (FROZEN):

Source: NCI Genomic Data Commons file 366f5822-7d50-4eae-8a40-1cf981a1ad9e (TCGA-23-1121.ED14039C-9ECF-4E01-9A1C-7A227847B8A3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).